Surgical pathology report (de-identified scan), TCGA case TCGA-64-5778, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-5778-01A (Primary Tumor).

[page 1 of 3]
Clinical History/Diagnosis: Right Lung Cancer

Source of Specimen(s):

- 1: 11R Lymph Nodes
- 2: Right Upper Lobe Bronchial Margins
- 3: 10R Lymph Nodes
- 4: 4R Lymph Nodes
- 5: 2R Lymph Nodes
- 6: 2R Highest Lymph Nodes
- 7: Level 7 Lymph Nodes

Gross Description:

Received in seven parts.

Source of Tissue: 1. Labeled #1, "11R lymph nodes"

Gross Description: Received fresh labeled, 11R lymph nodes". It consists of four soft black-brown anthracotic lymph nodes measuring from 0.3 up to 0.5 cm in greatest dimension. The lymph nodes are entirely submitted in 1A.

Source of Tissue: 2. Labeled #2, "right upper lobe"

Intraoperative Consultation: NEGATIVE MARGIN. NO TUMOR SEN PER DR.

Gross Description: Received fresh labeled ", right upper lobe". It consists of a lobe of lung weighing 238 grams and measuring 17 x 12.5 x 4.5 cm in greatest dimension. A 0.7 x 0.6 cm puckered area is identified approximately 4.5 cm from the stapled and vascular margins. The bronchial and vascular margins are grossly unremarkable. Multiple peribronchial lymph nodes are identified measuring from 0.1 up to 0.7 cm in greatest dimension. The specimen is sectioned to reveal a 3.7 x 2.5 x 2.5 cm ill-defined firm stellate mass at approximately 4.5 cm from the bronchial and vascular margins. The mass grossly corresponds to the previously described pleural puckering. The remaining lung parenchyma is red-brown, congested with no other masses present. The mass grossly does not appear to involve the bronchus. The bronchial margin is entirely frozen in 2FS. Additional random sections of the remainder of the specimen are submitted in 2A-2I.

Designation of Sections: 2FS- frozen section, 2A- vascular margins, 2B-2E- tumor with closest pleura inked blue, 2F- tumor with adjacent uninvolved parenchyma, 2G-2I- peribronchial lymph nodes

Source of Tissue: 3. Labeled #3, "10R lymph nodes"

Gross Description: Received fresh labeled ", 10R lymph nodes". It consists of a soft yellow-tan lymph node measuring 1.8 x 0.7 x 0.6 cm. The lymph node is serially sectioned and entirely submitted in 3A.

[page 2 of 3]
Source of Tissue: 4. Labeled #4, "4R lymph nodes"

CGA-64-5778

Gross Description: Received fresh labeled, 4R lymph nodes". It consists of a soft yellow-tan irregular fibrofatty tissue fragment measuring 5.5 x 3.5 x 1.5 cm. The specimen is serially sectioned to reveal multiple soft black-brown anthracotic lymph nodes measuring from 0.1 up to 0.7 cm in greatest dimension. The lymph nodes are entirely submitted in 4A-4E.

Source of Tissue: 5. Labeled #5, "2R lymph nodes"

Gross Description: Received fresh labeled, 2R lymph nodes". It consists of a soft yellow-tan irregular fibrofatty tissue fragment measuring 2.5 x 1.5 x 0.5 cm. The specimen is bisected and entirely submitted in 5A.

Source of Tissue: 6. Labeled #6, "2R highest lymph nodes"

Gross Description: Received fresh labeled ", 2R highest lymph nodes". It consists of multiple soft black-brown anthracotic lymph nodes measuring from 0.1 up to 0.5 cm in greatest dimension. The lymph nodes are entirely submitted in 6A.

Source of Tissue: 7. Labeled #7, "level 7 lymph nodes"

Gross Description: Received fresh labeled ", level 7 lymph nodes". It consists of multiple soft black-brown anthracotic lymph nodes measuring from 0.5 up to 0.7 cm in greatest dimension. The specimen is entirely submitted in 7A-7B.

Final Diagnosis:

1. 11R lymph nodes, excision:

- Five lymph nodes with no tumor seen (0/5).

2. Lung, right upper lobe, lobectomy:

- Adenocarcinoma, 3.7 cm, moderately differentiated.

- The tumor invades into the visceral pleura.

- Vascular invasion is identified.

- Twenty-four peribronchial lymph nodes with no tumor seen (0/24).

3. 10R lymph nodes, excision:

- Two lymph nodes with no tumor seen (0/2).

4. 4R lymph nodes, excision:

- Thirty-one lymph nodes with no tumor seen (0/31).

5. 2R lymph nodes, excision:

- Six lymph nodes with no tumor seen (0/6).

6. 2R highest lymph nodes, excision:

- Two lymph nodes with no tumor seen (0/2).

[page 3 of 3]
7. Level 7 lymph nodes, excision:
- Fourteen lymph nodes with no tumor seen (0/14).

LUNG TEMPLATE

TCGA-64-5778

Specimen Type
Lobectomy

Laterality
Right

Tumor Site
Upper lobe

Tumor Size
Greatest dimension: 3.7 cm (T1 if ≤ 3.0 cm; otherwise T2)

Histologic Type
Adenocarcinoma, non-mucinous bronchioloalveolar subtype

Histologic Grade
Moderately differentiated

Extension of Tumor
Carcinoma invades into/through visceral pleura (T2)

Venous (Large Vessel) Invasion
Absent

Arterial (Large Vessel) Invasion
Absent

Margins
Margins uninvolved by invasive carcinoma

Regional Lymph Nodes
84 regional lymph nodes examined
No regional lymph node metastasis

pTNM: T2 N0 Mx

Source: NCI Genomic Data Commons file ea1f8d02-e771-4695-b71f-cd4631c9f971 (TCGA-64-5778.36CF9846-5EC1-4D43-8B66-80A802C6B4E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).